Somatic mutation profile of tumor specimen TCGA-QQ-A5V2-01A (aliquot TCGA-QQ-A5V2-01A-11D-A32I-09) from TCGA case TCGA-QQ-A5V2, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant fibrous histiocytoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 42.2 years (15,420 days).
Specimen TCGA-QQ-A5V2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b56a46f-4c1d-4579-983f-f3a52474e87e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QQ-A5V2-10A (Blood Derived Normal), aliquot TCGA-QQ-A5V2-10A-01D-A32I-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64d2d1ca-baa3-4546-9c3e-36940e608bcd

The open-access MAF lists 14 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 10, Silent 2, Nonstop Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCKBR | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs1457572061, COSV58107266; called by muse, mutect2
- CHL1 | c.2554A>G p.T852A (on ENST00000397491 / NM_001253387.1; = p.T868A on NM_006614.4) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.122); catalogued as COSV99851122; called by muse, mutect2, varscan2
- DNAH5 | c.9604A>C p.R3202= | Splice Region (SNP) | VAF 7/20 reads (35%) | catalogued as COSV99449451; called by muse, mutect2
- EFCAB3 | c.89C>A p.P30Q | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV100540188; called by muse, mutect2, varscan2
- H3-3B | c.104G>T p.G35V | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.717); catalogued as COSV99637984; called by muse, varscan2
- KIAA1958 | c.1393G>A p.V465I | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as rs141479985; called by muse, mutect2, varscan2
- NOL9 | c.2109A>G p.*703Wext*5 | Nonstop Mutation (SNP) | VAF 21/65 reads (32%) | catalogued as COSV100891456; called by muse, mutect2, varscan2
- NUDT18 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.094); catalogued as rs368870753; called by muse, mutect2, varscan2
- PGM5 | c.1250T>C p.I417T | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101123913; called by muse, mutect2
- PPP1R3F | c.1813G>A p.G605R | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs201784162, COSV99278702; called by muse, mutect2, varscan2
- SYT3 | c.1580G>A p.G527E | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100144073; called by muse, mutect2
- TUBGCP5 | c.2680G>T p.V894L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CCDC184 | c.66G>A p.V22= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as COSV100343970; called by muse, mutect2, varscan2
- LARP1 | c.1128G>A p.T376= (on ENST00000518297 / NM_033551.3; = p.T299= on NM_015315.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 25/90 reads (28%) | catalogued as rs373569358; called by muse, mutect2, varscan2
